Somatic mutation profile of tumor specimen TARGET-10-PAPAGS-09A (aliquot TARGET-10-PAPAGS-09A-01D) from TARGET case TARGET-10-PAPAGS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.4 years (2,349 days).
Specimen TARGET-10-PAPAGS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd9b6217-8993-4355-b99d-428c8fca6457.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPAGS-10A (Blood Derived Normal), aliquot TARGET-10-PAPAGS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f8309c4-eb11-4e66-8f0b-a81c68c20606

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2049A>C p.R683S | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519723, COSV67569539, COSV67577012; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DPP3 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs199617262, COSV100855528; called by muse, varscan2
- IFIT2 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs757639216; called by muse, mutect2, varscan2
- RGS7 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs749609576, COSV100470752, COSV58543385; called by muse, mutect2, varscan2
- SOX6 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as rs760064805; called by muse, mutect2, varscan2
- ST7 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 46/106 reads (43%) | catalogued as rs759539749; called by muse, mutect2, varscan2
- CNTNAP2 | c.1217C>G p.P406R | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT tolerated (0.54); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- KRTAP19-1 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.341); called by muse, mutect2
- FAT3 | c.1746T>A p.A582= | Silent (SNP) | VAF 64/128 reads (50%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.352dup p.*118G | Silent (INS) | VAF 13/15 reads (87%) | called by mutect2, pindel*, varscan2*
- LINGO1 | c.630G>A p.A210= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as rs553512567; called by muse, mutect2, varscan2
